Somatic mutation profile of tumor specimen TCGA-85-A53L-01A (aliquot TCGA-85-A53L-01A-21D-A26M-08) from TCGA case TCGA-85-A53L, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.1 years (23,065 days).
Specimen TCGA-85-A53L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d43a2f6f-bb5e-4c4a-a481-5427b45275e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-A53L-10A (Blood Derived Normal), aliquot TCGA-85-A53L-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11ba0507-675b-4ff0-a92d-09c7f9be21a0

The open-access MAF lists 214 somatic variants for this specimen: 170 protein-altering or splice-affecting, 42 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 42, Nonsense Mutation 7, Splice Site 6, Frame Shift Del 4, Splice Region 2, Intron 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.602+1G>T p.X201_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | catalogued as rs794726827, CS032427, CS096271, COSV100321747, COSV57662425; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.994-2A>T p.X332_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | hotspot (GDC flag); catalogued as CS159286, COSV52692098, COSV52692518, COSV53122371; called by muse, mutect2, varscan2
- ABCA1 | c.1866G>T p.M622I | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101037529; called by muse, mutect2, varscan2
- ABCC11 | c.4127C>A p.T1376K | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100751089; called by muse, mutect2, varscan2
- ABHD14B | c.63C>G p.F21L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99865559; called by muse, mutect2, varscan2
- ACSS3 | c.1055G>C p.C352S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99699359; called by muse, mutect2, varscan2
- AHI1 | c.1010G>T p.C337F | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV99663550; called by muse, mutect2, varscan2
- ALOX5 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765467323, COSV65553396; called by muse, mutect2
- ANKRD17 | c.6338G>T p.G2113V | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.04); catalogued as COSV100429852; called by muse, mutect2, varscan2
- ANO4 | c.2477G>T p.S826I (on ENST00000392977 / NM_001286615.2; = p.S791I on NM_178826.4) | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1244974032, COSV54619238; called by muse, mutect2, varscan2
- APMAP | c.817G>C p.V273L | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV99468997; called by muse, mutect2, varscan2
- ARSJ | c.982A>C p.N328H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100193062; called by muse, mutect2, varscan2
- ASPM | c.6618A>T p.Q2206H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV99660968; called by muse, mutect2, varscan2
- B3GNT3 | c.747G>A p.W249* | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as rs865860468, COSV57952724; called by muse, mutect2, varscan2
- B3GNT4 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as COSV99928348; called by muse, mutect2, varscan2
- BAHD1 | c.805G>C p.A269P | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs368611692, COSV101346792; called by muse, mutect2, varscan2
- BIRC2 | c.575A>G p.H192R | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs182528901, COSV57160905; called by muse, mutect2, varscan2
- C1QTNF9 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV100130007, COSV59657665; called by muse, mutect2, varscan2
- C1orf56 | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs923365563, COSV99764779; called by muse, mutect2
- C4orf33 | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.173); catalogued as COSV99829015; called by muse, mutect2, varscan2
- CAMK1D | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV101123905; called by muse, mutect2, varscan2
- CAPN12 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100185501; called by muse, mutect2, varscan2
- CASS4 | c.2245C>G p.L749V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.221); catalogued as COSV100824879, COSV64388119; called by muse, mutect2
- CCDC74B | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.168); catalogued as COSV100134696; called by mutect2, varscan2
- CCT5 | c.165T>C p.N55= | Splice Region (SNP) | VAF 4/24 reads (17%) | catalogued as rs775126012, COSV99725562; called by mutect2, varscan2
- CD84 | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV100246240; called by muse, mutect2, varscan2
- CDC27 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); catalogued as COSV99296105; called by muse, mutect2, varscan2
- CDH10 | c.2292C>A p.Y764* | Nonsense Mutation (SNP) | VAF 26/132 reads (20%) | catalogued as COSV100052840, COSV52600483; called by muse, mutect2, varscan2
- CDH23 | c.4334A>T p.D1445V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99823325; called by muse, mutect2
- CFH | c.863A>G p.D288G | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV100661611, COSV62776461; called by muse, mutect2, varscan2
- CLVS1 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100370555; called by muse, mutect2, varscan2
- CNTNAP5 | c.2715T>A p.H905Q | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV101444047, COSV101444181, COSV70475058; called by muse, mutect2, varscan2
- COIL | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99538347; called by muse, mutect2, varscan2
- CPA6 | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99914516; called by muse, mutect2, varscan2
- CSMD2 | c.3165T>G p.F1055L | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV99594355; called by muse, mutect2, varscan2
- CSRP3 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.288); catalogued as COSV99788378; called by muse, mutect2, varscan2
- DBF4 | c.1109A>T p.E370V | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV99719557; called by muse, mutect2, varscan2
- DCAF4L2 | c.514C>A p.R172S | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100151233, COSV60476833; called by muse, mutect2, varscan2
- DNAH9 | c.1901+1G>T p.X634_splice | Splice Site (SNP) | VAF 15/60 reads (25%) | catalogued as COSV52383908; called by muse, mutect2, varscan2
- DNAH9 | c.11524T>A p.W3842R | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99307688; called by muse, mutect2, varscan2
- DNAJA3 | c.1090A>G p.R364G | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV99276963; called by muse, mutect2
- EIF2AK3 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100304054; called by muse, mutect2
- F13B | c.1316G>C p.C439S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100803408; called by muse, mutect2, varscan2
- FAF1 | c.1484T>C p.I495T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs1227112079, COSV100876019; called by muse, mutect2, varscan2
- FARP1 | c.2323C>T p.Q775* | Nonsense Mutation (SNP) | VAF 29/111 reads (26%) | catalogued as COSV100131928; called by muse, mutect2, varscan2
- FBN3 | c.6587A>T p.Y2196F | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.705); catalogued as COSV99561679; called by muse, mutect2, varscan2
- FBXO34 | c.1943G>T p.R648L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV58254210, COSV58255842; called by muse, mutect2, varscan2
- FLAD1 | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as rs939755698, COSV99422942; called by muse, mutect2, varscan2
- FMO4 | c.1426C>G p.P476A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100882150; called by muse, mutect2, varscan2
- FOLH1 | c.1855C>A p.P619T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99923812; called by muse, varscan2
- FTO | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101151093; called by muse, mutect2, varscan2
- FUBP3 | c.1278+1G>T p.X426_splice | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as COSV60515724; called by muse, mutect2
- FUT9 | c.569G>A p.C190Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100134172; called by muse, mutect2, varscan2
- GABRB1 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV99780376; called by muse, mutect2
- GCN1 | c.6101C>G p.S2034C | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100325604, COSV100325875; called by muse, mutect2, varscan2
- GRIK4 | c.554C>A p.S185Y | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.95); catalogued as COSV101483721; called by muse, mutect2, varscan2
- GRM5 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.873); catalogued as rs557855706, COSV59627388; called by muse, mutect2, varscan2
- HDLBP | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.037); catalogued as rs1375079473, COSV100191672; called by muse, mutect2, varscan2
- HNF4G | c.749C>A p.A250E (on ENST00000354370 / NM_001330561.2; = p.A297E on NM_004133.5) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100584940; called by muse, mutect2, varscan2
- HTT | c.7805A>G p.N2602S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV100751159; called by muse, mutect2, varscan2
- IGFN1 | c.1742C>A p.A581D (on ENST00000295591 / NM_001367841.1; = p.A3038D on NM_001164586.2) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.102); catalogued as COSV99813402; called by muse, mutect2, varscan2
- IGKV1-12 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs753214696; called by mutect2, varscan2
- IGKV1-17 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs530084333; called by muse, mutect2, varscan2
- IGSF1 | c.2492C>G p.A831G | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.089); catalogued as COSV100812279; called by muse, mutect2, varscan2
- ITPR3 | c.7951A>T p.T2651S | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.909); catalogued as COSV100952024; called by muse, mutect2, varscan2
- KCTD16 | c.539G>C p.G180A | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV101568865, COSV72578110; called by muse, mutect2, varscan2
- KDM4B | c.2906G>T p.R969M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99347203; called by muse, mutect2, varscan2
- KDM5C | c.231C>G p.A77= | Splice Region (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100855497; called by muse, mutect2, varscan2
- KIF26A | c.1916A>G p.E639G | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs941332150, COSV100181501; called by muse, mutect2, varscan2
- KIZ | c.616A>G p.S206G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV99852336; called by muse, mutect2, varscan2
- KLB | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV99962430; called by muse, mutect2, varscan2
- KLHL32 | c.1217G>C p.R406T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100987466, COSV65114746; called by muse, mutect2, varscan2
- KRTAP15-1 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); catalogued as COSV100481652; called by muse, mutect2, varscan2
- KSR2 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV100350912; called by muse, mutect2, varscan2
- LCA5 | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV100878354; called by muse, mutect2, varscan2
- LRP4 | c.2515C>G p.R839G | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101066828; called by muse, mutect2, varscan2
- LRRIQ1 | c.4720+1G>C p.X1574_splice | Splice Site (SNP) | VAF 3/13 reads (23%) | catalogued as COSV101280687; called by muse, mutect2
- LRRIQ4 | c.875T>A p.L292Q | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100540361; called by muse, mutect2, varscan2
- LYSMD3 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as COSV100270528; called by muse, mutect2
- MACF1 | c.11525A>G p.H3842R (on ENST00000372915; = p.H1775R on NM_012090.5) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as rs747734894, COSV99246379; called by muse, mutect2, varscan2
- MAGEB10 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV63311420; called by muse, mutect2, varscan2
- MAGIX | c.293A>C p.E98A | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.991); catalogued as COSV100891922; called by muse, mutect2, varscan2
- MAP2 | c.3257A>T p.Q1086L | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs1246870214, COSV99561477; called by muse, mutect2, varscan2
- MCEMP1 | c.447G>T p.M149I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV100365427; called by muse, mutect2, varscan2
- MSANTD4 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs772474973, COSV57284997; called by muse, mutect2, varscan2
- MYCBP2 | c.13276C>G p.L4426V (on ENST00000357337; = p.L4464V on NM_015057.5) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); catalogued as COSV100631551; called by muse, mutect2
- MYH8 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67973440; called by muse, mutect2, varscan2
- NCAM2 | c.2272G>T p.A758S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs1306281580, COSV99524883; called by muse, mutect2, varscan2
- NCOA6 | c.5014G>T p.G1672* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100750275; called by muse, mutect2, varscan2
- NF1 | c.5591G>T p.S1864I (on ENST00000358273 / NM_001042492.3; = p.S1843I on NM_000267.3) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100648087; called by muse, mutect2
- NHLRC1 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61481290; called by muse, mutect2
- NLGN1 | c.458G>T p.C153F | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100849964; called by muse, mutect2, varscan2
- NLGN1 | c.1403C>A p.P468Q | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100849965; called by muse, mutect2, varscan2
- NLGN1 | c.2122G>T p.V708F | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.257); catalogued as COSV100849966; called by muse, mutect2, varscan2
- NRAP | c.4134C>A p.D1378E (on ENST00000359988 / NM_001322945.2; = p.D1343E on NM_006175.4) | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV100748570; called by muse, mutect2, varscan2
- NTRK3 | c.1741G>C p.A581P | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100713698, COSV62310887; called by muse, mutect2, varscan2
- OR10J5 | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100604813; called by muse, mutect2, varscan2
- OR11L1 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.282); catalogued as COSV63313463; called by muse, mutect2
- OR13C3 | c.220G>T p.V74F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV101053354; called by muse, mutect2, varscan2
- OR4A15 | c.144G>A p.M48I | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100124326, COSV59035297; called by muse, mutect2, varscan2
- OR4A15 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.015); catalogued as COSV100124329, COSV59034345; called by muse, mutect2, varscan2
- OR4X1 | c.755G>A p.C252Y | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200439883, COSV100186812; called by muse, varscan2
- OR51G1 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1215613521, COSV58968767; called by muse, mutect2, varscan2
- OR6N2 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as COSV59412309, COSV59413557; called by muse, mutect2, varscan2
- OR8B4 | c.280G>T p.V94L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as COSV62069502; called by muse, mutect2, varscan2
- PAK5 | c.982A>C p.I328L | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV100781141, COSV100781636; called by muse, mutect2, varscan2
- PCDHGA2 | c.627C>A p.H209Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.034); catalogued as COSV99545312; called by muse, mutect2, varscan2
- PCDHGA9 | c.1855G>T p.V619L | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.209); catalogued as COSV99545322; called by muse, mutect2, varscan2
- PCLO | c.784A>T p.T262S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.006); catalogued as COSV100436766; called by muse, mutect2, varscan2
- PDGFRB | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99940914; called by muse, mutect2, varscan2
- PI3 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99714261; called by muse, mutect2, varscan2
- PIGR | c.1894G>C p.E632Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.412); catalogued as COSV100732602, COSV62903353; called by muse, mutect2, varscan2
- PIGR | c.1893G>T p.E631D | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV62903868; called by muse, mutect2, varscan2
- PLXNB2 | c.1102C>A p.H368N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV100834261; called by muse, mutect2, varscan2
- POLR1B | c.1493G>C p.C498S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99638387; called by muse, mutect2, varscan2
- PRG4 | c.1262C>G p.A421G | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100798301; called by muse, varscan2
- PTEN | c.425G>C p.R142P | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs753630034, CM132265, COSV100911161, COSV64291704; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PXDNL | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as rs776904737, COSV62477807; called by muse, mutect2, varscan2
- RALGAPB | c.3239G>T p.S1080I | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV99485683; called by muse, mutect2, varscan2
- RFX4 | c.1102G>T p.D368Y (on ENST00000392842 / NM_213594.3; = p.D274Y on NM_032491.6) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57578628, COSV99986264; called by muse, mutect2
- RHBDF2 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs1201037991, COSV100489376; called by muse, mutect2
- RSRC1 | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV55833931, COSV99906922; called by muse, mutect2, varscan2
- RTN2 | c.731G>C p.G244A | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.341); catalogued as COSV99839228; called by muse, mutect2, varscan2
- RYR3 | c.2639G>C p.W880S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101214082; called by muse, mutect2, varscan2
- RYR3 | c.2640G>T p.W880C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101214084, COSV66789809; called by muse, mutect2, varscan2
- S1PR1 | c.107A>G p.N36S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100541635; called by muse, mutect2, varscan2
- SALL3 | c.3854G>A p.R1285H | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as rs778334113, COSV73306140; called by muse, mutect2, varscan2
- SCN11A | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100182287; called by muse, mutect2, varscan2
- SCN2A | c.1031C>A p.A344E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99333148; called by muse, mutect2, varscan2
- SCN7A | c.2708G>T p.R903L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV101313343, COSV69270088; called by muse, mutect2, varscan2
- SDK1 | c.1978G>T p.A660S | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101269742; called by muse, mutect2, varscan2
- SFRP4 | c.541A>T p.K181* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV101460876, COSV101460940; called by muse, mutect2, varscan2
- SNCAIP | c.1462C>A p.H488N | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.346); catalogued as COSV99750020; called by muse, mutect2
- SPECC1 | c.2656G>T p.D886Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV54954320, COSV99822691; called by muse, mutect2, varscan2
- SPECC1L | c.1828G>C p.E610Q | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100063111; called by muse, mutect2, varscan2
- SPTBN1 | c.6524A>C p.K2175T | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.041); catalogued as COSV100443293; called by muse, mutect2, varscan2
- SRPRB | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs745490539; called by mutect2, varscan2
- STAB2 | c.4195T>C p.C1399R | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1459533277, COSV101186248; called by muse, mutect2
- SYCP2L | c.229A>G p.N77D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV99305716; called by muse, mutect2, varscan2
- SYNE1 | c.2999C>G p.A1000G (on ENST00000367255 / NM_182961.4; = p.A1007G on NM_033071.3) | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV99575911; called by muse, mutect2, varscan2
- TBC1D32 | c.3225G>T p.M1075I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99251052; called by muse, mutect2, varscan2
- TBK1 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100538363; called by muse, mutect2, varscan2
- TECPR2 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1230843715, COSV63970832; called by muse, mutect2, varscan2
- TENT4A | c.901G>T p.V301L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as COSV100049235; called by muse, mutect2, varscan2
- TGIF2LX | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV99383503; called by muse, mutect2, varscan2
- TM4SF1 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as COSV100543051, COSV59524872; called by mutect2, varscan2
- TMEM131 | c.1808C>T p.T603I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV99489302; called by muse, mutect2, varscan2
- TNKS | c.793G>T p.V265L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100127714; called by muse, mutect2, varscan2
- TTN | c.41275C>G p.Q13759E (on ENST00000591111; = p.Q6335E on NM_003319.4) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | PolyPhen probably damaging (0.979); catalogued as COSV100626584; called by muse, mutect2, varscan2
- TXNDC5 | c.880C>G p.L294V | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV101124356; called by muse, mutect2, varscan2
- UTP20 | c.4968G>C p.L1656F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99882394; called by muse, mutect2, varscan2
- VIT | c.1589C>A p.T530K (on ENST00000389975 / NM_001177969.1; = p.T545K on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV101007717, COSV64896697; called by muse, mutect2, varscan2
- VWA3A | c.2052C>G p.H684Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100241229, COSV55394883; called by muse, varscan2
- XIRP2 | c.5048C>T p.T1683M (on ENST00000628543; = p.T1858M on NM_152381.6) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); catalogued as rs111536641, COSV54685271; called by muse, mutect2, varscan2
- ZFHX4 | c.5200C>A p.Q1734K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99266664; called by muse, mutect2, varscan2
- ZMYM6 | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100451665; called by muse, mutect2, varscan2
- ZNF208 | c.2797A>T p.S933C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); catalogued as COSV101237183; called by muse, varscan2
- ZNF536 | c.920T>A p.F307Y | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as COSV62819898; called by muse, mutect2, varscan2
- ZNF783 | c.369G>T p.R123S | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV100954292; called by muse, mutect2, varscan2
- ZNF804B | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV100305720, COSV60832250; called by muse, mutect2, varscan2
- CARD11 | c.1632del p.T545Pfs*55 | Frame Shift Del (DEL) | VAF 27/120 reads (23%) | called by mutect2, pindel, varscan2
- CSMD3 | c.10350_10351del p.H3450Qfs*4 (on ENST00000297405 / NM_001363185.1; = p.H3281Qfs*4 on NM_052900.3) | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | called by mutect2, pindel, varscan2
- IGKV1-17 | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- IQCN | c.3115G>T p.A1039S | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.262); called by muse, mutect2
- MBOAT1 | c.336del p.F112Lfs*2 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- NID2 | c.3505_3509del p.A1169Sfs*8 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- SDR42E1 | c.333_335del p.R114del | In Frame Del (DEL) | VAF 17/79 reads (22%) | called by mutect2, pindel, varscan2
- TRAV26-2 | c.23C>G p.T8S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.124); called by muse, mutect2
- TRGV4 | c.348G>T p.W116C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBE2B | c.150_151+6del p.X50_splice | Splice Site (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- ABCA2 | c.5178G>T p.G1726= (on ENST00000614293; = p.G1696= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV99688329; called by muse, mutect2, varscan2
- ABCG8 | c.1692T>C p.N564= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV99700192; called by muse, mutect2, varscan2
- ADA | c.153C>A p.G51= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV100866638, COSV65739807; called by muse, mutect2, varscan2
- ADAMTSL3 | c.783G>C p.V261= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99720781; called by muse, mutect2, varscan2
- ADGRB1 | c.4419G>T p.R1473= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs1342260468, COSV60099012; called by muse, mutect2, varscan2
- ADHFE1 | c.1167C>T p.A389= | Silent (SNP) | VAF 33/171 reads (19%) | catalogued as rs765749948, COSV52554273; called by muse, mutect2, varscan2
- ARFGEF3 | c.2655G>A p.A885= | Silent (SNP) | VAF 28/157 reads (18%) | catalogued as rs760353560, COSV99294517; called by muse, mutect2, varscan2
- ASB15 | c.732G>A p.A244= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs373328275, COSV51925742, COSV51927855; called by muse, mutect2, varscan2
- CCDC150 | c.1929G>T p.A643= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV55876466, COSV99777309; called by muse, mutect2
- CDH6 | c.579C>T p.N193= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99420584; called by muse, mutect2, varscan2
- CEACAM20 | c.1503G>A p.E501= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100387012; called by muse, mutect2, varscan2
- CPA6 | c.1080A>C p.S360= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99914514; called by muse, mutect2, varscan2
- CTNND2 | c.2547C>A p.P849= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs774482007, COSV58889928, COSV58894490; called by muse, mutect2, varscan2
- FIG4 | c.2610A>G p.R870= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV100020167; called by muse, mutect2, varscan2
- GAB1 | c.423T>A p.A141= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99528747; called by muse, mutect2, varscan2
- GMPS | c.1956A>T p.T652= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV99903338; called by muse, mutect2, varscan2
- GRIK4 | c.555C>A p.S185= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV101483722; called by muse, mutect2, varscan2
- HTR3E | c.960G>A p.V320= (on ENST00000415389 / NM_001256613.1; = p.V335= on NM_182589.2) | Silent (SNP) | VAF 32/385 reads (8%) | catalogued as rs756004022; called by muse, mutect2
- IGFN1 | c.1743C>A p.A581= (on ENST00000295591 / NM_001367841.1; = p.A3038= on NM_001164586.2) | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99813406; called by muse, mutect2, varscan2
- IGHV3-74 | c.315G>T p.L105= | Silent (SNP) | VAF 97/251 reads (39%) | called by muse, mutect2, varscan2
- KLHL13 | c.1341T>C p.G447= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV53246774; called by muse, mutect2, varscan2
- LTN1 | c.4152T>C p.N1384= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs753420586, COSV100798155; called by muse, mutect2, varscan2
- MESP2 | c.1005G>A p.Q335= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs752972579, COSV100510841; called by muse, mutect2, varscan2
- MEX3A | c.1194C>G p.A398= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101348966; called by mutect2, varscan2
- MYO3B | c.2136A>T p.A712= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100511490; called by muse, mutect2, varscan2
- NCOA2 | c.1560C>T p.C520= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV101476050; called by muse, mutect2, varscan2
- NEK10 | c.3285C>G p.P1095= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99835611; called by muse, mutect2, varscan2
- NETO1 | c.618C>T p.I206= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV55015769; called by muse, mutect2, varscan2
- NLGN3 | c.1623T>C p.L541= (on ENST00000358741 / NM_181303.2; = p.L521= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100705015; called by muse, mutect2, varscan2
- PCDHGA12 | c.252G>A p.L84= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as rs144203659, COSV99341924; called by muse, mutect2, varscan2
- PIGR | c.774C>T p.A258= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV100732604; called by muse, mutect2, varscan2
- PPP4R1 | c.472C>T p.L158= (on ENST00000400556 / NM_001042388.3; = p.L141= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99553906; called by muse, mutect2, varscan2
- PRAMEF2 | c.639C>T p.H213= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV99535609; called by muse, mutect2, varscan2
- RSPH4A | c.474C>A p.P158= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV99994281; called by muse, mutect2, varscan2
- RTN1 | c.2088C>A p.V696= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99956640; called by muse, mutect2, varscan2
- RYR2 | c.11187C>A p.A3729= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100772420; called by muse, mutect2, varscan2
- SLC1A1 | c.1131A>T p.A377= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV99261548; called by muse, mutect2, varscan2
- SLC26A7 | c.615T>C p.Y205= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs146893680; called by muse, mutect2, varscan2
- SPTA1 | c.3330A>G p.L1110= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV100935451; called by muse, mutect2, varscan2
- STAB2 | c.840C>T p.P280= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV101186044, COSV101186247; called by muse, mutect2, varscan2
- TM4SF1 | c.408G>A p.E136= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100543050; called by mutect2, varscan2
- TRDN | c.87A>T p.G29= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1277480501, COSV100523209; called by muse, mutect2, varscan2
- CD300LD | c.40+45G>T | Intron (SNP) | VAF 44/93 reads (47%) | catalogued as rs372585810, COSV100032597; called by muse, mutect2, varscan2
- SETX | c.7287+183G>T | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99810714; called by muse, mutect2, varscan2
